Gene-level copy-number profile of tumor specimen TCGA-77-A5GA-01A from TCGA case TCGA-77-A5GA, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.0 years (27,762 days).
Specimen TCGA-77-A5GA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.8b01aa0b-1c7e-4218-ab2c-ae21534bac3a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-A5GA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/79ea01b8-503e-4d67-b412-4711d25bceef

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 11,872; copy number 2: 36,361; copy number 3: 8,784; copy number 4: 987; copy number 5: 761; copy number 6: 1,010.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-77-A5GA-01): tumor purity 0.26, ploidy 3.47, whole-genome doublings 1 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,967,752–26,644,595, 34 genes: CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1.
- chr17:142,789–386,254, 3 genes (within-gene range 0–6): DOC2B, LINC02091, RPH3AL.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,771 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,811,768–198,222,513, 1,167 genes, copy number 5–6 (broad region; genes not listed).
- chr16:46,469,341–52,280,638, 146 genes, copy number 5 (broad region; genes not listed).
- chr17:321,392–1,229,738, 29 genes, copy number 6 (within-gene range 3–6): AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1, C17orf97, RFLNB, AC015853.2, VPS53, AC015853.3, AC015853.1, AC027455.1, RPS4XP17, TLCD3A, GEMIN4, DBIL5P, GLOD4, AC087392.3, MRM3, AC087392.4, AC087392.5, NXN, AC087392.2, AC087392.1, AC036164.1, TIMM22, ABR, MIR3183, Metazoa_SRP.
- chr19:39,530,987–42,196,585, 150 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr19:54,031,412–57,974,534, 279 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,950. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
